Gene-level copy-number profile of tumor specimen ALCH-B3ZJ-TTP1-A from ALCHEMIST case ALCH-B3ZJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 44.6 years (16,288 days).
Specimen ALCH-B3ZJ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f2abd49a-a47d-413f-a370-fd744a9b900d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3ZJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/b6f9f47f-0999-44b5-8545-e6a572603e75

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 7,058; copy number 2: 48,178; copy number 3: 3,415; copy number 4: 13; copy number 5: 15; copy number 6: 3; copy number 8: 154; copy number 9: 2; copy number 13: 1; copy number 14: 3.

Homozygous deletions (total copy number 0; autosomes only): 67 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–2): AL139423.1.
- chr2:240,686,334–240,698,483, 2 genes: AC011298.1, AQP12A.
- chr7:5,592,816–5,606,655, 1 gene: FSCN1.
- chr9:130,892,707–130,896,812, 1 gene: QRFP.
- chr11:77,066,961–77,215,241, 3 genes: CAPN5, OMP, MYO7A.
- chr12:124,529,722–124,562,283, 5 genes (within-gene range 0–2): AC073592.7, AC073592.3, AC073592.9, AC073592.5, AC073592.6.
- chr15:25,169,337–25,250,940, 45 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:77,525,540–77,608,888, 2 genes: AC046168.1, AC046168.2.
- chr15:77,660,052–77,668,074, 1 gene (within-gene range 0–1): LINGO1-AS2.
- chr20:32,449,755–32,453,607, 1 gene (within-gene range 0–2): AL034550.1.
- chr20:63,939,829–63,956,985, 4 genes (within-gene range 0–1): UCKL1, MIR1914, MIR647, UCKL1-AS1.
- chr21:43,363,332–43,366,566, 1 gene: AP001046.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 178 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:72,504,806–75,670,185, 59 genes, copy number 8–14: AC104435.2, RNU1-62P, AC104435.1, RNA5SP136, SHQ1, AC134050.1, PSMD12P1, LAPTM4BP2, GXYLT2, Metazoa_SRP, FTH1P23, PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P, CCDC75P1, RNU6-1270P, PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1, AC108725.1, LINC02005, Metazoa_SRP, LINC02047, AC016930.1, AKR1B1P2, CNTN3, NIPA2P2, RN7SL294P, MIR4444-2, AC117481.1, HNRNPA3P6, MYLKP1, OR7E66P, OR7E22P, OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26.
- chr3:93,843,764–95,168,351, 14 genes, copy number 8: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879.
- chr3:166,160,021–170,860,993, 84 genes, copy number 8 (broad region; genes not listed).
- chr9:136,844,415–136,860,799, 3 genes, copy number 6 (within-gene range 4–6): AJM1, PHPT1, MAMDC4.
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr21:10,482,738–13,120,807, 11 genes, copy number 5 (within-gene range 3–5): AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:43,446,601–43,479,534, 3 genes, copy number 9–13 (within-gene range 9–18): LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 4,210. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
